CCDI case PBCGKM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ca5945e4-24b8-4dcc-b594-0852405ace41

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.9 years (3,264 days).

Biospecimens (3 samples)
- Sample 0DRL0O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRL0Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DRL1M: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
